Somatic mutation profile of tumor specimen TCGA-DI-A1NO-01A (aliquot TCGA-DI-A1NO-01A-31D-A159-09) from TCGA case TCGA-DI-A1NO, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 68.4 years (24,996 days).
Specimen TCGA-DI-A1NO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78e99e13-e96e-4152-8f99-7a962b8467f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DI-A1NO-11A (Solid Tissue Normal), aliquot TCGA-DI-A1NO-11A-11D-A159-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3b99496-d7eb-408e-a0da-bad18f5afaee

The open-access MAF lists 276 somatic variants for this specimen: 210 protein-altering or splice-affecting, 59 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 171, Silent 59, Frame Shift Del 15, Nonsense Mutation 10, Splice Site 7, Intron 3, RNA 2, Frame Shift Ins 2, Nonstop Mutation 2, 3'UTR 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA2 | c.5172G>A p.R1724= (on ENST00000614293; = p.R1694= on NM_001606.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 24/91 reads (26%) | catalogued as COSV99686782; called by muse, mutect2, varscan2
- ABHD16A | c.352C>G p.R118G | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101013106; called by muse, mutect2, varscan2
- ABLIM2 | c.1489A>T p.R497W (on ENST00000341937 / NM_001130084.2; = p.R446W on NM_032432.5) | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as COSV99588866; called by muse, mutect2, varscan2
- ACVR2A | c.675C>A p.D225E | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.041); catalogued as COSV99603835; called by muse, mutect2, varscan2
- ADGRL3 | c.1547C>G p.T516S (on ENST00000506720 / NM_001322402.2; = p.T448S on NM_015236.6) | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV101546828; called by muse, mutect2
- AGER | c.1088G>T p.W363L | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100426085; called by muse, mutect2, varscan2
- AKT2 | c.169G>T p.V57L | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.475); catalogued as COSV100251357, COSV60908025; called by muse, mutect2
- ALDH1B1 | c.1084G>T p.V362L | Missense Mutation (SNP) | VAF 57/84 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV100890886; called by muse, mutect2, varscan2
- APOB | c.4877T>G p.L1626* | Nonsense Mutation (SNP) | VAF 11/20 reads (55%) | catalogued as COSV99263350; called by muse, mutect2, varscan2
- APOB | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 38/40 reads (95%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99263352; called by muse, mutect2, varscan2
- ATP1B4 | c.854A>T p.Y285F (on ENST00000218008 / NM_001142447.3; = p.Y281F on NM_012069.5) | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.8); PolyPhen benign (0.38); catalogued as COSV99486121; called by muse, mutect2, varscan2
- ATP2B2 | c.2686G>C p.A896P (on ENST00000352432; = p.A862P on NM_001683.5) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV100659556; called by muse, mutect2, varscan2
- ATP7A | c.1104G>C p.L368F | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0.019); catalogued as COSV100430200; called by muse, mutect2, varscan2
- ATP8B2 | c.721C>G p.L241V (on ENST00000672630; = p.L208V on NM_001005855.2) | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100527621; called by muse, mutect2, varscan2
- B9D2 | c.490C>G p.L164V | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV99699056; called by muse, mutect2, varscan2
- BPTF | c.8813G>T p.R2938M | Missense Mutation (SNP) | VAF 138/141 reads (98%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100073918; called by muse, mutect2, varscan2
- BRINP3 | c.1606A>C p.T536P | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100818270; called by muse, mutect2, varscan2
- BUB1 | c.191A>G p.N64S | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV100240794; called by muse, varscan2
- C12orf45 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 31/81 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.427); catalogued as COSV99773967; called by muse, mutect2, varscan2
- C16orf87 | c.464G>C p.*155Sext*102 | Nonstop Mutation (SNP) | VAF 19/35 reads (54%) | catalogued as COSV99587449; called by muse, mutect2, varscan2
- C3orf56 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 70/75 reads (93%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs369125533, COSV67756305; called by muse, mutect2, varscan2
- CACNA1H | c.2201T>A p.V734D | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.261); catalogued as COSV100670639; called by muse, mutect2, varscan2
- CASP10 | c.1370G>A p.W457* (on ENST00000272879 / NM_032974.5; = p.W414* on NM_001230.5) | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as COSV99628630; called by muse, mutect2, varscan2
- CASR | c.2394C>A p.S798R (on ENST00000490131; = p.S875R on NM_000388.4) | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV99948409; called by muse, mutect2, varscan2
- CC2D2B | c.192C>G p.N64K | Missense Mutation (SNP) | VAF 20/22 reads (91%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV100729269; called by muse, mutect2, varscan2
- CD160 | c.469A>G p.T157A | Missense Mutation (SNP) | VAF 54/249 reads (22%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV52524395; called by muse, mutect2, varscan2
- CFAP52 | c.230A>T p.E77V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100234745; called by mutect2, varscan2
- CFDP1 | c.649G>C p.G217R | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.389); catalogued as rs367774683, COSV99382403; called by muse, mutect2, varscan2
- CHD4 | c.3254G>C p.G1085A (on ENST00000357008 / NM_001363606.2; = p.G1098A on NM_001273.5) | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100537251, COSV58903554; called by muse, mutect2, varscan2
- CHD6 | c.476A>G p.E159G | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV100497699; called by muse, mutect2, varscan2
- CLIC6 | c.1272G>T p.E424D | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV100659112; called by muse, mutect2, varscan2
- CNOT6 | c.1398C>G p.F466L | Missense Mutation (SNP) | VAF 27/29 reads (93%) | SIFT tolerated (0.39); PolyPhen benign (0.387); catalogued as COSV99993381; called by muse, mutect2, varscan2
- COG2 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.842); catalogued as COSV100794595, COSV64187464; called by muse, mutect2, varscan2
- CR1 | c.5093A>C p.D1698A | Missense Mutation (SNP) | VAF 71/131 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV100887371; called by muse, mutect2, varscan2
- CSAG1 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 92/214 reads (43%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.028); catalogued as COSV100756790; called by muse, mutect2
- CSMD2 | c.10442G>C p.S3481T | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as COSV99585473; called by muse, mutect2, varscan2
- CSMD2 | c.4261G>T p.A1421S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.403); catalogued as COSV99585476; called by muse, mutect2, varscan2
- CSTF2 | c.1650C>G p.D550E | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.91); PolyPhen probably damaging (0.995); catalogued as COSV100880625; called by muse, mutect2, varscan2
- CXorf56 | c.518A>T p.K173I (on ENST00000536133 / NM_001170570.2; = p.K187I on NM_022101.4) | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100233315; called by muse, mutect2, varscan2
- DDB1 | c.953A>C p.D318A | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100074233; called by muse, mutect2
- DDX60 | c.1307G>C p.C436S | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV101190222; called by muse, mutect2, varscan2
- DIAPH2 | c.1837C>G p.P613A | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100230484, COSV61260565; called by muse, mutect2, varscan2
- DMRTA1 | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.08); catalogued as COSV57923918; called by muse, mutect2, varscan2
- DMXL2 | c.8930T>A p.I2977N | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV99195930; called by muse, mutect2, varscan2
- DNAH10 | c.3007G>T p.E1003* (on ENST00000409039; = p.E942* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 32/96 reads (33%) | catalogued as COSV101291911; called by muse, mutect2, varscan2
- DNAH5 | c.9329C>A p.T3110K | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99444494; called by muse, mutect2, varscan2
- DNAH8 | c.2965del p.L989Ffs*5 | Frame Shift Del (DEL) | VAF 48/191 reads (25%) | catalogued as COSV59449510; called by mutect2, pindel, varscan2
- DNAJC25-GNG10 | c.370T>A p.C124S | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.998); catalogued as rs779628567, COSV100961330; called by muse, mutect2, varscan2
- DOHH | c.289G>C p.A97P | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99170973; called by muse, mutect2, varscan2
- DSCAM | c.4089C>A p.N1363K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68032945; called by muse, mutect2, varscan2
- ECPAS | c.155T>G p.V52G | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52203582, COSV99397422; called by muse, mutect2, varscan2
- ELFN2 | c.548C>A p.A183D | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.934); catalogued as COSV101297464; called by muse, mutect2, varscan2
- ELP1 | c.3931G>T p.D1311Y | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV101010308; called by muse, mutect2, varscan2
- ELP1 | c.1305G>C p.K435N | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.175); catalogued as COSV101010309, COSV65898496; called by muse, mutect2, varscan2
- ELP1 | c.824A>G p.H275R | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1564100993, COSV65900330; called by muse, mutect2, varscan2
- EML5 | c.952C>G p.L318V | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV100715005; called by muse, mutect2, varscan2
- EPB41L1 | c.1291C>A p.L431I | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.177); catalogued as COSV52437278, COSV99148835; called by muse, mutect2, varscan2
- FAM13C | c.506A>T p.E169V | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV99512982; called by muse, mutect2
- FAM216B | c.81T>A p.Y27* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as COSV100573032; called by muse, mutect2, varscan2
- FAT4 | c.12352G>T p.E4118* | Nonsense Mutation (SNP) | VAF 25/29 reads (86%) | catalogued as COSV100627162, COSV58678536; called by muse, mutect2, varscan2
- FCRL4 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV99619198; called by muse, mutect2, varscan2
- FOXRED2 | c.637G>C p.G213R | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99340645; called by muse, mutect2, varscan2
- FRAS1 | c.3592G>T p.D1198Y | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99347894; called by muse, mutect2, varscan2
- GABRA2 | c.1175C>G p.T392S | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.057); catalogued as COSV100733764; called by muse, mutect2, varscan2
- GALNT3 | c.1789C>G p.L597V | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.1); catalogued as COSV101204875; called by muse, mutect2, varscan2
- GLI3 | c.4466G>T p.S1489I | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV101229707; called by muse, mutect2, varscan2
- GLTP | c.473A>G p.K158R | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as COSV100570235; called by muse, mutect2, varscan2
- GPALPP1 | c.209G>C p.G70A | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100689107; called by muse, mutect2, varscan2
- GPR1 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 16/36 reads (44%) | catalogued as COSV101329825; called by muse, mutect2, varscan2
- H1-2 | c.587A>T p.K196M | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV100642223; called by muse, mutect2, varscan2
- H4C3 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as COSV100619476; called by muse, mutect2, varscan2
- HAMP | c.150+2T>G p.X50_splice | Splice Site (SNP) | VAF 29/70 reads (41%) | catalogued as COSV99723033; called by mutect2, varscan2
- HCN2 | c.843G>T p.K281N | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.763); catalogued as COSV99241209; called by muse, mutect2, varscan2
- HEG1 | c.2423C>G p.A808G | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV100229979; called by muse, varscan2
- HOXD9 | c.993C>G p.I331M | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99981687; called by muse, mutect2, varscan2
- INTS2 | c.1401G>T p.E467D | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV99247705; called by muse, mutect2
- IQCA1 | c.897C>G p.D299E | Missense Mutation (SNP) | VAF 49/52 reads (94%) | SIFT tolerated (0.39); PolyPhen benign (0.241); catalogued as COSV99608456; called by muse, mutect2, varscan2
- JAKMIP3 | c.1493C>T p.T498M | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.494); catalogued as rs923560323, COSV100058613; called by muse, mutect2, varscan2
- KALRN | c.3688T>C p.Y1230H | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99561960; called by muse, mutect2
- KIF21A | c.2985T>A p.N995K (on ENST00000361418 / NM_001378440.1; = p.N982K on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV100735262; called by muse, mutect2, varscan2
- KIFC2 | c.1094T>C p.L365P | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100023444; called by muse, mutect2, varscan2
- KLHL6 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100384258; called by muse, mutect2, varscan2
- KRT1 | c.1627G>A p.G543S | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.076); catalogued as COSV52868623; called by muse, mutect2, varscan2
- KRTAP12-4 | c.97A>T p.T33S | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100551728; called by muse, mutect2, varscan2
- L1TD1 | c.1771G>C p.E591Q | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.757); catalogued as COSV100776527, COSV63134129; called by muse, mutect2, varscan2
- LAMB1 | c.4385C>A p.S1462Y | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.92); PolyPhen benign (0.152); catalogued as COSV99739765; called by muse, mutect2, varscan2
- LGR6 | c.2420C>A p.A807D (on ENST00000367278 / NM_001017403.1; = p.A755D on NM_021636.3) | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV55164825, COSV99706425; called by mutect2, varscan2
- LHX2 | c.623C>G p.P208R | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV101010019; called by muse, varscan2
- LPL | c.674A>G p.K225R | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.8); PolyPhen benign (0.015); catalogued as CM043861, COSV100255252; called by muse, mutect2, varscan2
- LSM4 | c.253G>C p.A85P | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.43); catalogued as rs1291288423, COSV99416817; called by muse, mutect2, varscan2
- LTBR | c.668-2A>C p.X223_splice | Splice Site (SNP) | VAF 13/31 reads (42%) | catalogued as COSV99965165; called by muse, mutect2, varscan2
- LY96 | c.258T>A p.N86K | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755713901, COSV99514257; called by muse, mutect2, varscan2
- MACF1 | c.12590A>G p.E4197G (on ENST00000372915; = p.E2130G on NM_012090.5) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as COSV99240925; called by muse, mutect2, varscan2
- MAGEA4 | c.626C>A p.T209K | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV52342737, COSV99367261; called by muse, mutect2, varscan2
- MAMDC4 | c.1940C>G p.T647S | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as COSV100439774; called by muse, mutect2, varscan2
- MAP3K13 | c.1325G>T p.S442I | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV53997663, COSV99406328; called by muse, mutect2, varscan2
- MAP4K2 | c.2355C>A p.F785L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV99580240; called by muse, mutect2, varscan2
- MATN4 | c.1609G>T p.A537S (on ENST00000372754; = p.A496S on NM_003833.4) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | PolyPhen probably damaging (1); catalogued as COSV100636837; called by muse, mutect2, varscan2
- MELTF | c.1766C>T p.P589L | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.34); catalogued as COSV99585772; called by muse, mutect2, varscan2
- MORN5 | c.170T>C p.I57T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101055641; called by mutect2, varscan2
- MXRA8 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.805); catalogued as rs1323479044, COSV100491810; called by muse, mutect2, varscan2
- MYF6 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 25/46 reads (54%) | catalogued as COSV57351944, COSV99952641; called by muse, mutect2, varscan2
- MYO18A | c.1505G>C p.S502T | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.686); catalogued as COSV100571881; called by muse, mutect2, varscan2
- MYOM3 | c.3620A>G p.D1207G | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100141527; called by muse, mutect2, varscan2
- MYOM3 | c.2321C>G p.A774G | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100292388; called by muse, mutect2, varscan2
- MYOM3 | c.2320G>T p.A774S | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as COSV100292389; called by muse, mutect2, varscan2
- NECAB2 | c.1039A>T p.R347W | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100533815; called by muse, mutect2, varscan2
- NEO1 | c.1003C>T p.L335F | Missense Mutation (SNP) | VAF 43/43 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as rs753578613, COSV99981210; called by muse, mutect2, varscan2
- NETO1 | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as rs1267926349, COSV55001858, COSV55012005; called by muse, mutect2, varscan2
- NEUROD6 | c.887C>A p.P296H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as COSV99773832; called by mutect2, varscan2
- NLRP1 | c.2908G>C p.E970Q | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV52573472, COSV99332853; called by muse, mutect2, varscan2
- NOS1 | c.3007C>A p.L1003I | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV100499917, COSV100499965; called by muse, mutect2
- NRXN3 | c.2291C>T p.T764I (on ENST00000335750 / NM_001330195.2; = p.T391I on NM_004796.6) | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100200395; called by muse, mutect2, varscan2
- NUFIP1 | c.50C>G p.S17C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.257); catalogued as COSV100742109; called by muse, mutect2, varscan2
- NUP62CL | c.544G>C p.A182P | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100990930; called by muse, mutect2, varscan2
- NUTM1 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1324412558, COSV100148815; called by muse, mutect2, varscan2
- OPN1SW | c.703C>A p.Q235K | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV99975425; called by muse, mutect2, varscan2
- OPRK1 | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT tolerated (0.46); PolyPhen benign (0.03); catalogued as rs200159306, COSV55568063; called by muse, mutect2, varscan2
- OR10A2 | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.27); catalogued as rs754733341, COSV100224921; called by muse, mutect2, varscan2
- OR2C1 | c.385C>G p.P129A | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100514830; called by muse, mutect2, varscan2
- OR2D3 | c.836A>T p.N279I | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.492); catalogued as COSV99549161; called by muse, mutect2, varscan2
- PAPPA | c.1688A>T p.E563V | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV100072750; called by muse, mutect2, varscan2
- PAX9 | c.244A>T p.T82S | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.484); catalogued as COSV64062009; called by muse, mutect2, varscan2
- PCDHB8 | c.1395C>A p.N465K | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV99175440; called by muse, mutect2, varscan2
- PHEX | c.138T>A p.S46R | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.025); catalogued as COSV101039373; called by muse, mutect2, varscan2
- PHLDB1 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 49/52 reads (94%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100616228; called by muse, mutect2, varscan2
- PINK1 | c.665G>A p.W222* | Nonsense Mutation (SNP) | VAF 19/114 reads (17%) | catalogued as rs777160388, COSV100387128; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKHD1 | c.6959C>T p.S2320F | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100580922; called by muse, mutect2, varscan2
- PKHD1 | c.3296C>T p.A1099V | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.714); catalogued as COSV100580924; called by muse, mutect2, varscan2
- POLDIP3 | c.913del p.A305Pfs*12 | Frame Shift Del (DEL) | VAF 8/67 reads (12%) | catalogued as COSV99349202; called by mutect2, pindel, varscan2
- PPP1R3A | c.2699C>T p.S900F | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV52888355; called by muse, mutect2, varscan2
- PRAME | c.133C>G p.L45V | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV101287005, COSV67161690; called by muse, mutect2, varscan2
- PSMB4 | c.713C>A p.T238N | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.414); catalogued as COSV99304778; called by muse, mutect2, varscan2
- RABL2A | c.619G>A p.V207M | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.051); catalogued as rs751779979, COSV100905618; called by muse, varscan2
- RBM15B | c.1758G>T p.L586F | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.46); PolyPhen benign (0.055); catalogued as rs1553621906, COSV100081882; called by muse, mutect2, varscan2
- RNF213 | c.2356G>T p.A786S | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.033); catalogued as COSV100172974; called by muse, mutect2, varscan2
- ROCK1 | c.1156G>C p.A386P | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV67694893; called by muse, mutect2
- ROS1 | c.2000C>A p.T667N | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as COSV100876321; called by muse, mutect2, varscan2
- RPN2 | c.1600G>C p.E534Q | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99411370; called by muse, mutect2, varscan2
- RRAGB | c.400T>G p.Y134D (on ENST00000262850 / NM_016656.4; = p.Y106D on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV99469006; called by muse, mutect2, varscan2
- SAGE1 | c.1076C>G p.P359R | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV100186587; called by muse, mutect2, varscan2
- SAMD9L | c.2649T>G p.C883W | Missense Mutation (SNP) | VAF 41/56 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV100560270; called by muse, mutect2, varscan2
- SEMA3B | c.473C>G p.P158R | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV100312686; called by muse, mutect2, varscan2
- SEPTIN4 | c.917A>C p.K306T | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.842); catalogued as COSV100400202; called by muse, mutect2, varscan2
- SHOC1 | c.1400A>C p.K467T | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV59507113; called by muse, mutect2, varscan2
- SLC12A6 | c.958G>A p.V320I (on ENST00000354181 / NM_001365088.1; = p.V269I on NM_005135.2) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.673); catalogued as rs752427635, COSV99270892; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC28A2 | c.1906G>C p.E636Q | Missense Mutation (SNP) | VAF 89/98 reads (91%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV100754591; called by muse, mutect2, varscan2
- SLC7A4 | c.581T>A p.L194H | Missense Mutation (SNP) | VAF 38/56 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1422312690, COSV100298502; called by muse, mutect2, varscan2
- SLC9B1 | c.218T>C p.I73T | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as rs79959710, COSV56467915; called by muse, mutect2
- SLCO4A1 | c.933G>T p.W311C | Missense Mutation (SNP) | VAF 100/592 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99414432; called by muse, mutect2, varscan2
- SNTG1 | c.219+1del | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as COSV52456932; called by mutect2, pindel, varscan2
- SOAT1 | c.177+2C>G p.X59_splice | Splice Site (SNP) | VAF 10/65 reads (15%) | catalogued as COSV100858864; called by muse, mutect2, varscan2
- SPATA31E1 | c.4271G>A p.S1424N | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.15); PolyPhen benign (0.346); catalogued as COSV57796043; called by muse, mutect2, varscan2
- SPTA1 | c.6937G>T p.D2313Y | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as rs1307185698, COSV100934154; called by muse, mutect2, varscan2
- SPTA1 | c.6206C>T p.P2069L | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100934155; called by muse, mutect2, varscan2
- SPTBN2 | c.3826G>C p.D1276H | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100018065; called by muse, mutect2, varscan2
- STPG2 | c.286A>T p.K96* | Nonsense Mutation (SNP) | VAF 28/31 reads (90%) | catalogued as COSV99757844; called by muse, mutect2, varscan2
- SYMPK | c.2331G>T p.E777D | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV99841338; called by muse, mutect2, varscan2
- TADA1 | c.387T>A p.D129E | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100902283; called by muse, mutect2
- TECTB | c.128A>T p.E43V | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); catalogued as COSV101027621; called by muse, mutect2, varscan2
- TENM3 | c.5720C>A p.S1907Y | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101304836; called by muse, mutect2, varscan2
- TFDP1 | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.999); catalogued as rs745662661, COSV100945703; called by muse, mutect2, varscan2
- TFRC | c.1501C>G p.L501V | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV100786383, COSV64054019; called by muse, mutect2, varscan2
- THSD7B | c.2183G>A p.R728H | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs370266523; called by muse, mutect2, varscan2
- TMC3 | c.1349A>G p.E450G | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV100845831; called by muse, mutect2, varscan2
- TMEM44 | c.315C>A p.F105L | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV99861511; called by muse, mutect2, varscan2
- TNFRSF13B | c.505C>T p.L169F | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV99891127; called by muse, mutect2, varscan2
- TNFRSF21 | c.1769G>A p.R590H | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs778427574, COSV57280254; called by muse, mutect2, varscan2
- TOX4 | c.1373A>C p.Q458P | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99398001; called by muse, mutect2, varscan2
- TTK | c.1832G>T p.S611I | Missense Mutation (SNP) | VAF 86/87 reads (99%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as COSV100035938; called by muse, mutect2, varscan2
- TTN | c.54649A>G p.T18217A (on ENST00000591111; = p.T10793A on NM_003319.4) | Missense Mutation (SNP) | VAF 24/42 reads (57%) | PolyPhen probably damaging (0.994); catalogued as COSV100592581; called by muse, mutect2, varscan2
- TXNDC8 | c.110G>T p.R37M | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.97); PolyPhen benign (0.026); catalogued as COSV100995409; called by muse, mutect2, varscan2
- UBE2N | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as rs1293576319, COSV100538534; called by muse, mutect2, varscan2
- WBP2 | c.175T>G p.F59V | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99637330; called by muse, mutect2, varscan2
- XPNPEP2 | c.1613G>A p.G538E | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64369689; called by muse, mutect2, varscan2
- YWHAB | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV99407470; called by muse, mutect2, varscan2
- ZBTB4 | c.1856C>T p.S619L | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as COSV100262613; called by muse, mutect2, varscan2
- ZCCHC12 | c.85C>A p.L29M | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.26); catalogued as COSV100038392; called by muse, mutect2, varscan2
- ZMYND8 | c.2684T>A p.L895Q (on ENST00000311275 / NM_001363741.2; = p.L869Q on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.372); catalogued as COSV99519448; called by muse, mutect2, varscan2
- ZNF284 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as rs779545394, COSV69690722; called by muse, mutect2, varscan2
- ZNF3 | c.353A>G p.K118R | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.091); catalogued as COSV99447069; called by muse, mutect2, varscan2
- ZNF423 | c.2719G>A p.V907M (on ENST00000563137 / NM_001379286.1; = p.V899M on NM_015069.4) | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.813); catalogued as rs1279629000, COSV99279556; called by muse, mutect2, varscan2
- ZNF556 | c.1257G>T p.Q419H | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56910805; called by muse, mutect2, varscan2
- ZNF582 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV100018462; called by muse, mutect2, varscan2
- ZNF676 | c.859T>C p.C287R (on ENST00000650058; = p.C255R on NM_001001411.3) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101236094; called by muse, varscan2
- ZP4 | c.1008C>A p.Y336* | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | catalogued as COSV100850532; called by muse, mutect2, varscan2
- ZSCAN5B | c.626C>G p.T209R | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100748327; called by muse, varscan2
- ZWINT | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 57/100 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs754852712, COSV59184784; called by muse, mutect2, varscan2
- ABCB4 | c.1166_1171del p.S389_I390del | In Frame Del (DEL) | VAF 16/24 reads (67%) | called by mutect2, varscan2
- ANKRD13C | c.1003_1004del p.I335Ffs*15 | Frame Shift Del (DEL) | VAF 15/63 reads (24%) | called by mutect2, pindel, varscan2
- C1orf216 | c.174del p.R59Gfs*60 | Frame Shift Del (DEL) | VAF 5/35 reads (14%) | called by mutect2, pindel, varscan2
- CLEC12B | c.92-8_96del p.X31_splice | Splice Site (DEL) | VAF 19/104 reads (18%) | called by mutect2, pindel, varscan2
- CLPX | c.359-9_372del p.X120_splice | Splice Site (DEL) | VAF 20/57 reads (35%) | called by mutect2, pindel, varscan2
- CLSTN2 | c.2359-8_2359del p.X787_splice | Splice Site (DEL) | VAF 19/160 reads (12%) | called by mutect2, pindel, varscan2
- DACH2 | c.1715del p.N572Tfs*19 | Frame Shift Del (DEL) | VAF 17/45 reads (38%) | called by mutect2, varscan2
- DENND5B | c.3623del p.L1208* | Frame Shift Del (DEL) | VAF 23/45 reads (51%) | called by mutect2, pindel, varscan2
- DMAC1 | c.322_*3del | Nonstop Mutation (DEL) | VAF 11/51 reads (22%) | called by mutect2, pindel, varscan2
- EIF2AK3 | c.1566_1590del p.W522Cfs*5 | Frame Shift Del (DEL) | VAF 21/77 reads (27%) | called by mutect2, pindel, varscan2
- GYS2 | c.633_646del p.R211Sfs*4 | Frame Shift Del (DEL) | VAF 19/55 reads (35%) | called by mutect2, pindel, varscan2
- HNRNPA1 | c.*1_*4+7del | Splice Site (DEL) | VAF 22/182 reads (12%) | called by mutect2, varscan2
- HPD | c.684_703del p.V229Hfs*7 | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | called by mutect2, pindel, varscan2
- INPPL1 | c.3585_3592dup p.E1198Gfs*7 | Frame Shift Ins (INS) | VAF 36/166 reads (22%) | called by mutect2, varscan2
- LRP12 | c.2294_2312del p.S765Mfs*6 | Frame Shift Del (DEL) | VAF 14/92 reads (15%) | called by mutect2, varscan2
- MUC3A | c.9147C>A p.F3049L | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.801); called by muse, varscan2
- PRKRIP1 | c.267_268delinsC p.E89Dfs*46 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | called by pindel, varscan2*
- QKI | c.185dup p.N62Kfs*13 | Frame Shift Ins (INS) | VAF 56/100 reads (56%) | called by mutect2, pindel, varscan2
- RYK | c.237_285del p.D80Yfs*6 | Frame Shift Del (DEL) | VAF 18/122 reads (15%) | called by mutect2, pindel
- SCNN1G | c.701_728del p.Y234Wfs*7 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel
- TMEM236 | c.1002C>A p.F334L | Missense Mutation (SNP) | VAF 75/157 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TP53 | c.628_632del p.N210Ffs*4 | Frame Shift Del (DEL) | VAF 42/44 reads (95%) | called by mutect2, varscan2
- AGAP2 | c.2802C>T p.I934= (on ENST00000547588 / NM_001122772.2; = p.I578= on NM_014770.4) | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV99222140; called by muse, mutect2, varscan2
- BICDL1 | c.387G>C p.R129= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV101287134; called by muse, mutect2, varscan2
- C1R | c.507G>A p.E169= (on ENST00000536053 / NM_001354346.2; = p.E155= on NM_001733.7) | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV56925443; called by muse, mutect2
- CACNA1H | c.2202C>A p.V734= | Silent (SNP) | VAF 29/53 reads (55%) | catalogued as COSV100670642, COSV61992885; called by muse, mutect2, varscan2
- CALN1 | c.615C>A p.V205= (on ENST00000329008 / NM_001017440.3; = p.V247= on NM_031468.4) | Silent (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- CCDC57 | c.819C>G p.T273= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV101051787; called by muse, mutect2, varscan2
- CCNB3 | c.522G>A p.K174= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV99328382; called by muse, mutect2, varscan2
- CDHR3 | c.312G>A p.Q104= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV100487921; called by muse, mutect2, varscan2
- CEACAM5 | c.156T>C p.L52= | Silent (SNP) | VAF 56/259 reads (22%) | catalogued as rs782457186, COSV99703710; called by muse, mutect2, varscan2
- CHRNA1 | c.1230C>T p.P410= (on ENST00000261007 / NM_001039523.3; = p.P385= on NM_000079.4) | Silent (SNP) | VAF 42/121 reads (35%) | catalogued as COSV99650139; called by muse, mutect2, varscan2
- COL4A6 | c.2664G>T p.G888= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV100563241; called by muse, mutect2, varscan2
- CPA1 | c.195C>T p.V65= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as rs782422328, COSV99163214; called by muse, mutect2, varscan2
- DOCK11 | c.267A>G p.P89= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV99352763; called by muse, mutect2, varscan2
- DST | c.16839G>A p.R5613= (on ENST00000361203 / NM_001374722.1; = p.R3310= on NM_015548.5) | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as COSV99750570; called by muse, mutect2, varscan2
- ESPL1 | c.3138C>G p.L1046= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV99228845; called by muse, mutect2, varscan2
- ESRP1 | c.1545C>T p.D515= | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as rs777955065, COSV100619138; called by muse, mutect2, varscan2
- F2 | c.684C>A p.T228= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV100319307, COSV61317678; called by muse, mutect2, varscan2
- FAAH | c.285C>A p.A95= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV54544040, COSV54544512; called by muse, mutect2, varscan2
- FBXO10 | c.603C>G p.V201= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV99446198; called by muse, mutect2, varscan2
- HHIP | c.1635C>A p.G545= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as COSV99666524; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1761T>A p.I587= | Silent (SNP) | VAF 26/47 reads (55%) | catalogued as COSV100780686; called by muse, mutect2, varscan2
- KCND2 | c.1032C>T p.Y344= | Silent (SNP) | VAF 30/104 reads (29%) | catalogued as rs1490973208, COSV58568917, COSV58575538; called by muse, mutect2, varscan2
- LUZP4 | c.861C>A p.L287= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV100904830, COSV100904835; called by muse, mutect2, varscan2
- MIA2 | c.2076T>A p.V692= | Silent (SNP) | VAF 24/172 reads (14%) | catalogued as COSV99697231; called by muse, mutect2, varscan2
- MMP9 | c.465C>A p.T155= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100812336; called by muse, mutect2, varscan2
- MUC2 | c.489C>A p.T163= | Silent (SNP) | VAF 22/64 reads (34%) | called by muse, mutect2, varscan2
- N4BP2 | c.2275A>C p.R759= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV99788146, COSV99789441; called by muse, mutect2, varscan2
- NBEA | c.5910G>T p.L1970= | Silent (SNP) | VAF 43/47 reads (91%) | catalogued as COSV100076442, COSV59782049; called by muse, mutect2, varscan2
- PCSK9 | c.429C>T p.I143= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as rs368511429; called by muse, mutect2, varscan2
- PKD1L2 | c.2694G>T p.L898= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as COSV100216047; called by muse, mutect2, varscan2
- PLEKHO2 | c.918T>G p.G306= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100060549; called by muse, mutect2, varscan2
- PRKAG3 | c.1011G>T p.L337= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs1456874099, COSV99291733; called by muse, mutect2, varscan2
- PRRG3 | c.66G>A p.E22= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV100948540, COSV64851493; called by muse, mutect2, varscan2
- PSMC3 | c.1011C>A p.I337= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as rs909068465, COSV100099266; called by muse, mutect2, varscan2
- PSMG3 | c.351G>T p.R117= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV99365798; called by muse, mutect2, varscan2
- RABL6 | c.1134C>G p.V378= | Silent (SNP) | VAF 29/146 reads (20%) | catalogued as rs758910661, COSV100272757; called by muse, mutect2, varscan2
- RCSD1 | c.483G>A p.T161= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs373490112; called by muse, mutect2, varscan2
- RFTN2 | c.78G>A p.P26= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs376638860; called by muse, mutect2, varscan2
- RHBDF2 | c.657C>A p.L219= | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as COSV100489166; called by muse, mutect2, varscan2
- RPAP3 | c.1941C>T p.D647= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV99139256; called by muse, mutect2, varscan2
- SH3BGR | c.33T>C p.P11= | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as COSV100374324; called by muse, mutect2, varscan2
- SLC14A2 | c.2589C>A p.P863= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV99674962; called by muse, mutect2, varscan2
- SLC22A1 | c.1089G>T p.G363= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as COSV61452012; called by muse, mutect2, varscan2
- SLC32A1 | c.21C>T p.S7= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV99461728; called by muse, mutect2, varscan2
- SLC49A4 | c.366G>C p.L122= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as rs770000276, COSV99658833; called by muse, mutect2, varscan2
- SLC7A4 | c.582C>A p.L194= | Silent (SNP) | VAF 37/54 reads (69%) | catalogued as COSV100298501; called by muse, mutect2, varscan2
- SNX25 | c.2223T>A p.I741= | Silent (SNP) | VAF 21/101 reads (21%) | catalogued as COSV99252286; called by muse, mutect2, varscan2
- STAT6 | c.888G>T p.L296= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as COSV100273046; called by muse, mutect2, varscan2
- STK32C | c.459G>A p.L153= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV100061737; called by mutect2, varscan2
- STMN3 | c.60C>A p.L20= | Silent (SNP) | VAF 41/205 reads (20%) | catalogued as COSV64247164; called by muse, mutect2, varscan2
- TMOD3 | c.759G>C p.V253= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV100418998; called by muse, mutect2, varscan2
- TNC | c.3243C>T p.T1081= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as rs373432241; called by muse, mutect2, varscan2
- TTN | c.1368T>G p.T456= | Silent (SNP) | VAF 54/83 reads (65%) | catalogued as COSV100592584; called by muse, mutect2, varscan2
- TUBGCP5 | c.1789C>T p.L597= | Silent (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- UBR5 | c.2646C>T p.R882= | Silent (SNP) | VAF 10/142 reads (7%) | catalogued as COSV99639181; called by muse, mutect2
- UGCG | c.54C>A p.L18= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as COSV100958903; called by muse, mutect2, varscan2
- VMO1 | c.87G>T p.R29= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV54496534, COSV99564532; called by muse, mutect2, varscan2
- VMP1 | c.1090T>C p.L364= | Silent (SNP) | VAF 26/202 reads (13%) | catalogued as COSV99229877; called by muse, mutect2, varscan2
- WASHC5 | c.963A>C p.S321= | Silent (SNP) | VAF 133/137 reads (97%) | catalogued as COSV100572478; called by muse, mutect2, varscan2
- DNM3 | c.1911+14497A>C | Intron (SNP) | VAF 19/89 reads (21%) | catalogued as COSV100797747; called by muse, mutect2, varscan2
- MIR31 | n.49T>A | RNA (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- RAPH1 | c.733-8401_733-8384del | Intron (DEL) | VAF 7/20 reads (35%) | called by mutect2, varscan2
- THSD4 | c.1016-70047G>A | Intron (SNP) | VAF 43/86 reads (50%) | called by muse, mutect2, varscan2
- TSPOAP1 | chr17:58331246 C>T | 5'Flank (SNP) | VAF 51/52 reads (98%) | called by muse, mutect2, varscan2
- TUBB7P | n.156C>A | RNA (SNP) | VAF 17/129 reads (13%) | called by muse, mutect2, varscan2
- UVSSA | c.*9710A>C | 3'UTR (SNP) | VAF 114/398 reads (29%) | catalogued as COSV100245803; called by muse, mutect2, varscan2
